Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A91Y, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A91Y-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Adenocarcinoma, tubular 8211/3
Site: Gastric antrum C16.3
JW 3/15/14

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Antrum)

1- Lymph node 12p:

Involved by neoplasia (1/1), with capsular transposition.

2-Stomach:

Adenocarcinoma with the following features:

Site: body and antrum.

Histologic patterns:

Tubular

Histologic grade: III, poorly differentiated

Lauren classification: intestinal type

Largest tumor size: 9.0 cm.

Ulceration: present

Local invasion to:

Serosa

Proximal margin

Uninvolved by neoplasia

Distal margin

Exiguous, with neoplastic glands distant 1 mm from surgical margin

Neural invasion

Present

Lymphatic invasion

Present

Blood vessel invasion

Present

Greater omentum

Uninvolved by neoplasia

Lymph nodes:

Report of examined lymph nodes according to standardization, JGCA-1998:

F- Chain 1 – right paracardic: uninvolved by neoplasia (0/2).

G- Chain 2 – left paracardic: uninvolved by neoplasia (0/3).

H- Chain 3 – lesser curvature: involved by neoplasia (16/18), with capsular transposition.

I – Chain 4sa – short gastric vessels: uninvolved by neoplasia (0/1).

J – Chain 4sb – left gastroepiploic vessels: involved by neoplasia (2/4).

K – Chain 4d – right gastroepiploic vessels: involved by neoplasia (7/7).

U – Chain 12a – hepatoduodenal ligament (hepatic artery): involved by neoplasia (1/1).

L – Chain 5 – suprapyloric: involved by neoplasia (1/1).

[page 2 of 2]
M – Chain 6 – infrapyloric: involved by neoplasia (11/11).
N – Chain 7 – left gastric artery: involved by neoplasia (4/4).
O- Chain 8a – anterior hepatic artery (antero-superior group): involved by neoplasia (3/3).
Q- Chain 9 – celiac trunk: involved by neoplasia (4/4).
S- Chain 11p – proximal splenic artery: involved by neoplasia (1/1).
W-Chain 12p – hepatoduodenal ligament (behind portal vein): involved by neoplasia (4/4)

3- Esophageal margin:
Uninvolved by neoplasia.

4- Peritoneum from cardia:
Uninvolved by neoplasia.

5-Mesenteric lymph node:
Uninvolved by neoplasia (0/1).

6-Hepatogastric ligament:
Uninvolved by neoplasia.

Primary/Secondary Site Discrepancy		✓
HPAR Discrepancy		✓
Dual/Mixed/Concurrent Primary Nodes		✓

Source: NCI Genomic Data Commons file ca45c2c3-4a3c-422b-a793-7395e4712075 (TCGA-VQ-A91Y.AD6B1D21-62C9-4EC6-9801-A07C71C22667.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).